Surgical pathology report (de-identified scan), TCGA case TCGA-MI-A75G, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site BLN - Baylor, specimen TCGA-MI-A75G-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinoma, hepatocellular NOS
817013
Site: Liver
C22.0

-- SURGICAL PATHOLOGY ----

MEDICAL RECORD

SURGICAL PATHOLOGY

PATHOLOGY REPORT

Laboratory:

Accession No.

Submitted by:

Date obtained:

Specimen (Received)

A. GALLBLADDER

B. RIGHT HEPATECTOMY WITH ADRENALECTOMY

BRIEF CLINICAL HISTORY:

PREOPERATIVE DIAGNOSIS:

HCC

OPERATIVE FINDINGS:

POSTOPERATIVE DIAGNOSIS:

HCC

Surgeon/physician:

PATHOLOGY REPORT

Laboratory:

Accession No.

GROSS DESCRIPTION:

A. The specimen consists of a 10.5 x 4.2 x 4.0 cm, intact gallbladder displaying a 0.6 x 0.4 x 0.4 cm attached, clamped, patent cystic duct. The serosa is tan-pink to yellow-green, smooth and glistening with minimal bile staining. Opening reveals multiple tan-yellow, bosselated choleliths ranging from 0.3 to 0.8 cm in greatest dimensions with abundant amounts of dark green viscous bile. The mucosa is dark green and granular. Wall thickness averages 0.3 cm. Representative sections are submitted in cassettes 1 and 2.

B. The specimen consists of a 555 gram, 13.8 x 11.5 x 6.0 cm, partial hepatectomy specimen displaying a tan-brown, scabrous hepatic resection margin. The capsule is tan-pink to red, and smooth with an underlying bulging mass displays in the capsule measuring 4.5 x 4.5 cm. There is an attached segment of soft tissue measuring 6.0 x 3.2 x 1.0 cm that is designated by the surgeon as adhered adrenal gland. The hepatic resection margin is inked. The specimen is serially sectioned to reveal a 4.5 x 4.0 x 2.6 cm, tan-yellow to green, lobulated, well-circumscribed solitary mass that is 0.8 cm from the closest hepatic resection margin. The mass is grossly confined to the hepatic parenchyma and displays the overlying hepatic capsule. The mass does not extend into the adrenal or the periadrenal fat.

Remaining hepatic parenchyma is tan-brown and granular. No subsequent lesions are identified. The attached adrenal gland has an approximated weight of 8.2 grams, and displays a tan-brown to golden yellow cut surface.

Representative sections are submitted as follows: B1-B3- mass to closest hepatic resection margin; B4-B5- mass to overlying adrenal gland and hepatic capsule; B6-B7- mass to adjacent uninvolved hepatic parenchyma; B-8 mass with overlying hepatic capsule; B9- hepatic parenchyma away from mass.

MICROSCOPIC EXAM

DIAGNOSIS:

A. Gallbladder, cholecystectomy:

[page 2 of 2]
- CHOLELITHIASIS
- CHRONIC CHOLECYSTITIS

B. Liver, right hepatectomy with adrenalectomy:
- HEPATOCELLULAR CARCINOMA

- SPECIMEN: Liver and right adrenal gland
- PROCEDURE: Partial hepatectomy
- TUMOR SIZE: 4.5 x 4.0 x 2.6 cm
- TUMOR FOCALITY: Solitary
- HISTOLOGIC TYPE: Hepatocellular carcinoma
- HISTOLOGIC GRADE: Grade 2 (Edmondson and Steiner)
- TUMOR EXTENSION: Tumor confined to the liver
- MARGINS:
- Parenchymal Margin: Uninvolved by invasive carcinoma
- LYMPHOVASCULAR INVASION:
- MACROSCOPIC VENOUS INVASION: Not identified
- MICROSCOPIC SMALL VESSEL INVASION: Identified
- PERINEURAL INVASION: Not identified
- PATHOLOGIC TNM STAGING:
- PRIMARY TUMOR: pT2
- ADDITIONAL PATHOLOGIC FINDINGS:
- Chronic hepatitis with cirrhosis, Grade 3, Stage 4
- Fibrosis Score: Knodell 4/4, Metavir 4/4, Ishak 6/6
- Right adrenal gland, no evidence of malignancy

concur with the diagnosis.

staff pathologist
Signed

Source: NCI Genomic Data Commons file 3a2a239d-5233-44d0-b82a-3efdaf89647d (TCGA-MI-A75G.30FAEBBF-0EEE-40F5-9463-50FDDE258D4B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).